Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q2, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q2-01A (Primary Tumor).

[page 1 of 2]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Follicular neoplasm of thyroid (4.9 cm nodule).

Specimens Submitted:

1: Total thyroid

DIAGNOSIS:

1. Total thyroid:

Tumor Type:

Papillary carcinoma, follicular variant

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 4.9 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

ICD-0-3

carcinoma, papillary, follicular variant

8340/3

Site: thyroid, NOS C73.9

JW
8/31/11

[page 2 of 2]
Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not Identified

Lymph Nodes:

Number of nodes examined:1

One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "total thyroid" and consists of a thyroid weighing 37 g. The right lobe measures 6 x 3.5 x 3 cm, the left lobe measures 3.5 x 2.5 x 1.5 cm and the isthmus measures 1 x 0.5 x 0.3 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a well-circumscribed, thinly encapsulated, solid, tan mass in the right lobe with dimensions of 4.9 x 3.5 x 2 cm. There is focal central cystic change. There is also a separate well circumscribed, tan nodule in the left lobe with dimensions of 0.8 x 0.6 x 0.6 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

MRL- mass right lobe

NLL- nodule left lobe

RL - right lobe

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Total thyroid

Block	Sect. Site	PCs
1	IS	2
4	LL	4
9	MRL	9
2	NLL	2
4	RL	4

Source: NCI Genomic Data Commons file 6d17172d-807d-4a67-a37a-d25e3b208eb6 (TCGA-DJ-A2Q2.B7ACF926-7983-4DBC-8017-F85BCC85AC70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).